Surgical pathology report (de-identified scan), TCGA case TCGA-67-6216, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site St Joseph's Medical Center (MD), specimen TCGA-67-6216-01A (Primary Tumor).

[page 1 of 3]
PRIORITY: FROZEN SEC

TCGA-67-6216

SURGICAL PROCEDURES:

LUNG-LOBECTOMY, REGIONAL LYMPH

CLINICAL HISTORY

PERTINENT CLINICAL HISTORY: RIGHT MIDDLE LOBE MASS

GROSS DESCRIPTION

A. The specimen is submitted fresh for frozen section as "right middle lobe - please assess resection margins (TCGA)" and consists of a wedge shaped segment of lung measuring 10 x 4.5 x 2.5 cm. The surgical margin exhibits a line of metallic staples measuring 9 cm. The pleural surface is pink and smooth. After removal of the staples, there are several ligated vessels which measure up to 0.4 cm in length and 0.3 cm in diameter. Sectioning of the lung exhibits pink slightly air filled tissue exhibiting a firm pale white tumor measuring 1.8 x 1.3 x 0.9 cm. The tumor approaches to within approximately 2 cm from the bronchial margin. Representative sections are submitted in 9 cassettes as follows:

Cassette 1:	Bronchial margin and vessel margin
Cassettes 2-5:	Tumor showing surrounding normal parenchyma and bronchus
Cassette 6:	Remaining small segments of tumor not used for TCGA studies
Cassettes 7 and 8:	Normal lung
FSP:	Used for frozen section

FROZEN SECTION DIAGNOSIS: Right middle lobe: Adenocarcinoma extending to within 3-4 mm of the parenchymal margin and > 2 cm of bronchial margin.

B. The specimen is submitted fresh as "right middle lobar node" and consists of a gray black lymph node measuring 1 cm in dimension; bisected and submitted in toto; 2 (1).

[page 2 of 3]
GROSS DESCRIPTION

(Continued)

TCGA-67-6216

C. The specimen is submitted fresh as "right lower lobar node" and consists of a gray black lymph node measuring 1.3 cm in dimension; bisected and submitted in toto; 2 (1).

FINAL DIAGNOSIS

- A. RIGHT MIDDLE LOBE (LOBECTOMY SPECIMEN): MODERATELY DIFFERENTIATED GLAND FORMING AND PAPILLARY ADENOCARCINOMA WITH FOCAL PSAMMOMA BODY FORMATION, GRADE II, 1.8 CM MAXIMUM DIAMETER. THE TUMOR IS CONFINED WITHIN THE LUNG, AND EXTENDS TO WITHIN APPROXIMATELY 4 MM OF THE PARENCHYMAL MARGIN AT ITS CLOSEST APPROACH AND > 2 CM FROM THE BRONCHIAL MARGIN. VASCULAR MARGINS AND FOUR HILAR LYMPH NODES ARE FREE OF DISEASE. RANDOM SECTIONS OF THE REMAINING LUNG ARE UNREMARKABLE.
- B. RIGHT MIDDLE LOBAR LYMPH NODE: SINGLE LYMPH NODE WITH NO EVIDENCE OF MALIGNANCY.
- C. RIGHT LOWER LOBAR LYMPH NODE: SINGLE LYMPH NODE WITH NO EVIDENCE OF MALIGNANCY.

SYNOPTIC REPORT

SYNOPTIC REPORT: LUNG
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: LOBECTOMY
SPECIMEN INTEGRITY: INTACT
LATERALITY: RIGHT
TUMOR SITE: MIDDLE LOBE
TUMOR SIZE: 1.8 CM
TUMOR FOCALITY (SPECIFY): UNIFOCA
HISTOLOGIC TYPE: ADENOCARCINOMA
HISTOLOGIC GRADE: II
EXTENT OF INVASION: CONFINED WITHIN LUNG
EXTENSION TO PLEURA/OTHER STRUCTURES (SPECIFY): NOT IDENTIFIED
ADDITIONAL PERTINENT FINDINGS - ATELECTASIS, PNEUMONIA, ETC: (SEE NARRATIVE)

MARGINS:

BRONCHIAL: UNINVOLVED
PARENCHYMAL: UNINVOLVED
VASCULAR: UNINVOLVED
OTHER MARGINS (PARIETAL PLEURAL/CHEST WALL, ETC., IF APPLICABLE): N/A

[page 3 of 3]
SYNOPTIC REPORT

(Continued)

DISTANCE TO PERTINENT MARGIN(S) (AS APPLICABLE): 4 MM FROM STAPLED
PARENCHYMAL MARGIN

NEOADJUVANT TREATMENT EFFECT (IF APPLICABLE): N/A

VENOUS INVASION: NOT IDENTIFIED
ARTERIAL (LARGE VESSEL) INVASION: NOT IDENTIFIED
LYMPHATIC INVASION: NOT IDENTIFIED

LYMPH NODE (INCLUDING 10:S19905):

N1 - # INVOLVED/# EXAMINED: 0/6
N2 - # INVOLVED/# EXAMINED: 0/4+
N3 - # INVOLVED/# EXAMINED: 0/1+

OTHER PERTINENT FINDINGS: (SEE NARRATIVE)

pTNM STAGE: pT1a N0 MX

Source: NCI Genomic Data Commons file 977a3e0d-1ce1-4bfc-8264-cc8fd134b083 (TCGA-67-6216.9F6AC234-E3D8-44A9-B82D-0552E49224BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).